Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70V, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70V-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology	Final Results
--------------------	---------------

Surgical Pathology

Final

CASE NUMBER: :

DIAGNOSIS:

Adrenal gland, right, adrenalectomy: Pheochromocytoma.

NOTE: Tumor cells are positive for synaptophysin and chromogranin.
MIB-1 immunostain demonstrates a low proliferation index.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: pheochromocytoma
Specimen Taken For Protocol:
01 - Yes Allocate Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: pheochromocytoma Post-Operative
Diagnosis:
same Operative Findings: see op note

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT

GROSS DESCRIPTION: Received fresh in a container labeled with the patient's name, medical record number, and "right adrenal gland" is an intact ovoid tan-pink nodule (7.5 x 5.5 x 3 cm) and 97.4 grams. The external surface has an attenuated adrenal gland 6.5 x 1.5 x 0.5 cm. The external surface is inked black. The nodule is bisected revealing a hemorrhagic friable maroon-pink cut surface. Gross photographs are taken. Approximately 50% of tissue from the center of the nodule is procured for research with the majority to and approximately a 3-mm piece to Approximately one-fourth of the normal-appearing gland is procured for . The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. The procurement was performed by . The specimen is received in Surgical Pathology and matches the above description. The tumor is sampled and representative sections are placed in white cassettes

Gross Description dictated by
Gross Description dictated by i

Additional

[page 2 of 2]
Surgical Pathology [C

Final Results

No consultants
Accessioned: (
Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974

JobID:

Do not file in Medical Record

Requested By:

Source: NCI Genomic Data Commons file 41a00573-9844-4222-b6ab-40b98a8b24f2 (TCGA-QR-A70V.BC0F8B7A-A87F-46C4-9816-A5B9E434B88A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).